Surgical pathology report (de-identified scan), TCGA case TCGA-66-2755, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Indivumed, specimen TCGA-66-2755-01A (Primary Tumor).

[page 1 of 2]
Examination report

Macroscopic findings:

1. (a-f) Right upper lobe of lung: pulmonary lobe weighing 287 g and measuring 180 x 120 x 60 mm with bronchus removed close to the parenchyma. Adhesions on the exterior. On the costal side, deformed parietal pleura containing adipose tissue. In the apical section of S 1 there is a tumorous node measuring 65 mm, grayish-white, containing significant anthracotic pigment, with a well demarcated border and polycyclic demarcation, extending up to and under the adhered pleura. The bronchia are free of tumors in their central branches and are unremarkable. The right middle pulmonary lobe is also unremarkable. No larger lymph nodes are detectable either in the hilar or peribronchial areas.
2. L 4: Torn lymph node tissue with anthracotic pigment, measuring around 10 mm.
3. L 10: Nodule measuring 3 mm with blackish pigment.
4. L 7: segmented lymph adipose tissue, with partial black pigmentation, measuring approx 20 mm when spread out flat.
5. (a-b) L 4: segmented lymph adipose tissue, measuring approx 20 mm when spread out flat, likewise with partial black pigmentation; one of the lymph nodes has a suspicious grayish-white border.
6. (a-b) L 3: segmented lymph adipose tissue, with partial black pigmentation, measuring approx 20 mm when spread out flat.

Microscopic findings:

1. (HE, b: PAS, b - e: EvG) No signs of tumor in the resection margin of the bronchia or the adipose connective tissue and blood vessels by it. In the peribronchial area there is a small tumor-free lymph node with anthracotic pigment. The described tumor is made up of bands of an immature, squamous cell carcinoma with distinct pleomorphism and chromatin coarsening of the core as well as frequent mitosis and multifocal necrotic inclusions. Infiltration of the visceral pleura, penetrating the adjoining adhesion area, however the clearly definable parietal pleura and the adjoining, adhered, subpleural adipose connective tissue have no further tumorous branches. Significant indication of angioinvasion in the centre of the tumor with formation of obliterative tumor thrombi.
2. (HE) Further, tumor-free lymph nodes with histiocytosis, cicatrization and significant anthracotic pigment deposition.
3. (HE) similar to 2.
4. (HE) similar to 2.
5. (HE) similar to 2. Follicle with activated, large germinal centre with nuclear detritus macrophages.
6. (HE) similar to 2.

Diagnosis: Resected right superior pulmonary lobe with poorly differentiated and non-keratinizing, maturing squamous cell carcinoma, measuring a maximum of 65 mm, with the main tumor mass in S 1 with infiltration of the visceral pleura and, in the perifocal section, inflamed and scarred adherent cusp of parietal pleura with subpleural adipose tissue, without tumorous branches. Multifocally, angioinvasion in the centre of the tumor with vascular tumor thrombi; the bronchial resection margin as well as the peribronchial lymph nodes are tumor-free, the latter with anthracosis. All further lymph nodes are tumor-free with varying degrees of distinct anthracosis.

[page 2 of 2]
Tumor classification:

M-8070/3, G 3, pT 2, pV 1, pN 0, pM X, stage I B. R 0.

Right upper lobe of lung

Lymph nodes

Source: NCI Genomic Data Commons file ce031f06-5971-4652-91f1-388ddd4c0c94 (TCGA-66-2755.BBAE44D1-526F-4DAD-9224-CF2DC56D0852.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).